Somatic mutation profile of tumor specimen TCGA-CJ-4638-01A (aliquot TCGA-CJ-4638-01A-02D-1386-10) from TCGA case TCGA-CJ-4638, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 46.8 years (17,110 days).
Specimen TCGA-CJ-4638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 280f9f6b-fe92-4ad9-87b5-523e6a7c3fc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4638-11A (Solid Tissue Normal), aliquot TCGA-CJ-4638-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc23933-27f3-42b3-8665-74148c282872

The open-access MAF lists 72 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 13, Nonsense Mutation 3, Frame Shift Del 3, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 83/159 reads (52%) | catalogued as rs1553646284, COSV56230759; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 107/199 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CD962176, CM056724, CM114396, COSV56542752, COSV56558534; called by muse, mutect2, varscan2
- AASS | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 162/444 reads (36%) | catalogued as COSV62788926; called by muse, varscan2
- ABCD2 | c.1745G>C p.R582P | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.112); catalogued as COSV58049600; called by muse, mutect2, varscan2
- ADAMTS5 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV53175743, COSV53185907; called by muse, mutect2
- ADGRV1 | c.7190T>A p.V2397E | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV67978697; called by muse, mutect2, varscan2
- ANO2 | c.2752G>A p.V918I (on ENST00000356134 / NM_001278597.3; = p.V922I on NM_001278596.3) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs781231821, COSV59008268; called by muse, mutect2, varscan2
- APOB | c.2832G>T p.L944F | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV51923679; called by muse, mutect2, varscan2
- BMP7 | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV101215401, COSV67779576; called by muse, mutect2, varscan2
- CACNA1C | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59697521; called by muse, mutect2, varscan2
- CACNA1E | c.6822T>A p.H2274Q (on ENST00000367573 / NM_001205293.3; = p.H2231Q on NM_000721.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV100704472; called by muse, varscan2
- CD86 | c.642G>C p.M214I (on ENST00000330540 / NM_175862.5; = p.M208I on NM_006889.4) | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV52605187, COSV52610547; called by muse, mutect2, varscan2
- CECR2 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836337; called by muse, mutect2, varscan2
- COL4A5 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 133/525 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60356306; called by muse, mutect2, varscan2
- DENND1C | c.1970C>G p.S657C | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); catalogued as COSV57567938; called by muse, mutect2, varscan2
- DPP4 | c.515T>G p.I172S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62105091; called by muse, mutect2, varscan2
- EPHB6 | c.1237G>T p.G413C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV67417336; called by muse, mutect2, varscan2
- ETV6 | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV67148223; called by muse, mutect2, varscan2
- GAREM1 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs370225304; called by muse, mutect2, varscan2
- GBA2 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV62305281; called by muse, mutect2
- HECTD1 | c.2701A>C p.K901Q | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV65991127; called by muse, mutect2, varscan2
- JMJD6 | c.559C>A p.H187N | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57970225; called by muse, mutect2, varscan2
- KCNT1 | c.3438T>A p.N1146K (on ENST00000488444; = p.N1127K on NM_001272003.2) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV99706407; called by muse, mutect2
- KCNV2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs1471161378, COSV66055556; called by muse, mutect2, varscan2
- KIAA0586 | c.3065C>T p.S1022F (on ENST00000619416 / NM_001244190.2; = p.S961F on NM_014749.5) | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV54171302; called by muse, mutect2, varscan2
- KL | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1321884076, COSV66307868; called by muse, mutect2, varscan2
- KLHL42 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67145628; called by muse, mutect2, varscan2
- MCM3AP | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52436369; called by muse, mutect2, varscan2
- MCTS1 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV64892219; called by muse, mutect2
- MRE11 | c.1879A>G p.T627A (on ENST00000323929 / NM_005591.4; = p.T599A on NM_005590.4) | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV60573563; called by muse, mutect2
- MUTYH | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV58343498; called by muse, mutect2, varscan2
- NF2 | c.516+1G>C p.X172_splice | Splice Site (SNP) | VAF 14/218 reads (6%) | catalogued as CS951485, COSV58520205, COSV58520231, COSV58520946; called by muse, mutect2
- OR10H5 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58277448; called by muse, mutect2, varscan2
- PAK2 | c.922A>G p.N308D | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV59079203; called by muse, mutect2
- PER1 | c.2564A>G p.Y855C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs749259305, COSV57917354; called by muse, mutect2, varscan2
- PREX1 | c.960C>G p.I320M | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV64247914; called by muse, mutect2, varscan2
- QSOX1 | c.1604T>G p.F535C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62579638; called by muse, mutect2, varscan2
- RLF | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.473); catalogued as COSV65650647; called by muse, mutect2, varscan2
- SCRN1 | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54128430; called by muse, mutect2, varscan2
- SEC24C | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs751417221, COSV59539977; called by muse, mutect2, varscan2
- SETD5 | c.4240T>C p.Y1414H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1200288249, COSV56707555; called by muse, mutect2, varscan2
- SMAD2 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50992800, COSV50993078; called by muse, mutect2
- SORBS2 | c.3243G>A p.G1081= (on ENST00000284776 / NM_021069.5; = p.G647= on NM_003603.6) | Splice Region (SNP) | VAF 14/156 reads (9%) | catalogued as rs1470342176, COSV52991391; called by muse, mutect2
- SPTAN1 | c.4615C>T p.Q1539* | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | catalogued as COSV63985482; called by muse, mutect2, varscan2
- SYNE1 | c.15259C>T p.R5087W (on ENST00000367255 / NM_182961.4; = p.R5016W on NM_033071.3) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs767636254, COSV54909831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM87A | c.830A>T p.Y277F | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67746271; called by muse, mutect2
- TRIM75P | c.338T>G p.M113R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV72295799; called by muse, mutect2, varscan2
- TTN | c.15836A>C p.E5279A (on ENST00000591111; = p.E4352A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/245 reads (6%) | PolyPhen benign (0.036); catalogued as COSV59893538, COSV59920215; called by muse, mutect2
- USP51 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 106/329 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV72351487, COSV72352016; called by muse, mutect2, varscan2
- XKR6 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1436029265, COSV58654469; called by muse, mutect2, varscan2
- XRN2 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV65868142; called by muse, mutect2
- ZNF611 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60539558; called by muse, mutect2, varscan2
- CNOT1 | c.5433_5436del p.V1812Cfs*8 | Frame Shift Del (DEL) | VAF 46/144 reads (32%) | called by mutect2, pindel, varscan2
- HTR1F | c.930dup p.V311Cfs*7 | Frame Shift Ins (INS) | VAF 25/123 reads (20%) | called by mutect2, varscan2
- RELN | c.3291_3300del p.C1098Sfs*18 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | called by mutect2, pindel, varscan2
- SECISBP2 | c.1468_1471del p.A490Qfs*8 | Frame Shift Del (DEL) | VAF 15/145 reads (10%) | called by mutect2, pindel
- UNC13B | c.3064C>T p.H1022Y | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ANKRD17 | c.6882A>T p.S2294= | Silent (SNP) | VAF 120/323 reads (37%) | catalogued as COSV58215557; called by muse, mutect2, varscan2
- BCAS3 | c.219A>T p.T73= | Silent (SNP) | VAF 98/264 reads (37%) | catalogued as COSV66770179; called by muse, mutect2, varscan2
- CLCA1 | c.1452G>A p.Q484= | Silent (SNP) | VAF 93/260 reads (36%) | catalogued as COSV52325112; called by muse, mutect2, varscan2
- IL33 | c.303C>G p.V101= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as rs931333412, COSV67342715; called by muse, mutect2
- LRRC17 | c.819T>G p.L273= | Silent (SNP) | VAF 14/250 reads (6%) | catalogued as COSV50864051; called by muse, mutect2
- MATN2 | c.1584T>C p.S528= | Silent (SNP) | VAF 98/334 reads (29%) | catalogued as COSV54707004; called by muse, mutect2, varscan2
- MSMP | c.183C>T p.R61= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs758771580, COSV65238856; called by muse, mutect2, varscan2
- NEIL3 | c.1806T>A p.I602= | Silent (SNP) | VAF 66/156 reads (42%) | catalogued as rs1264564811, COSV52808598; called by muse, mutect2, varscan2
- OR4C12 | c.180C>T p.F60= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV58859427; called by muse, mutect2, varscan2
- PSMA8 | c.81G>A p.A27= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs570532077, COSV100378604, COSV57601056; called by muse, mutect2, varscan2
- PTPMT1 | c.507C>A p.I169= | Silent (SNP) | VAF 65/178 reads (37%) | catalogued as COSV58596704; called by muse, mutect2, varscan2
- RTL4 | c.798C>T p.L266= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV61205633; called by muse, mutect2, varscan2
- SLC7A4 | c.729C>G p.S243= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV60382472; called by muse, mutect2, varscan2
- CCDC61 | c.-8C>A | 5'UTR (SNP) | VAF 10/150 reads (7%) | catalogued as COSV54427688; called by muse, mutect2
- MIR518D | n.39del | RNA (DEL) | VAF 68/181 reads (38%) | catalogued as rs1568624059; called by mutect2, varscan2
